Somatic mutation profile of tumor specimen TCGA-FU-A3HZ-01A (aliquot TCGA-FU-A3HZ-01A-11D-A20U-09) from TCGA case TCGA-FU-A3HZ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G3; Age at diagnosis: 64.5 years (23,565 days).
Specimen TCGA-FU-A3HZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ffc705c-b9b9-4418-99b9-05eea5982756.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FU-A3HZ-10A (Blood Derived Normal), aliquot TCGA-FU-A3HZ-10A-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d592694c-0e0a-4916-bfee-d8f48b1405e6

The open-access MAF lists 2,120 somatic variants for this specimen: 1,733 protein-altering or splice-affecting, 343 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,496, Silent 343, Nonsense Mutation 184, Splice Site 25, Intron 21, RNA 15, Splice Region 10, Nonstop Mutation 5, 3'UTR 5, Frame Shift Del 5, Frame Shift Ins 4, In Frame Del 3.

Variants (750 of 2,120; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, varscan2
- BRD7 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as rs796065051, COSV54264750; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CFTR | c.3310G>T p.E1104* | Nonsense Mutation (SNP) | VAF 22/72 reads (31%) | catalogued as rs397508538, CM1212244, CM950255, COSV50043254; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 10/36 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- FUBP1 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408536007, COSV53927182; called by muse, mutect2, varscan2
- MTOR | c.6644C>A p.S2215Y | Missense Mutation (SNP) | VAF 11/28 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MVK | c.1039+2T>C p.X347_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as rs398122910, CS128665, COSV57331093; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PPP3CA | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1553923787, COSV59920640; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 26/49 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.90085C>T p.R30029* (on ENST00000591111; = p.R22605* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as rs1322596650, COSV59932918; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.56572C>T p.R18858* (on ENST00000591111; = p.R11434* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 26/64 reads (41%) | catalogued as rs869312112, CM121824, COSV59933111; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- USP53 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as rs751511532, COSV56792977; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WDR45 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as rs886041382, CM1211563, COSV59875580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.452); catalogued as COSV55746439; called by muse, mutect2
- ABCA10 | c.2007T>A p.F669L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV52219389; called by mutect2, varscan2
- ABCA12 | c.679A>G p.K227E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV55951990; called by muse, mutect2, varscan2
- ABCA13 | c.2911T>C p.Y971H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs759671430, COSV70026569; called by muse, mutect2, varscan2
- ABCA13 | c.6589A>C p.N2197H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV70026576; called by muse, mutect2, varscan2
- ABCA13 | c.7714G>T p.E2572* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV71284445, COSV71284538; called by muse, mutect2, varscan2
- ABCA5 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as rs758687342, COSV67016050; called by muse, mutect2
- ABCA6 | c.2627A>C p.Y876S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV52636586; called by muse, mutect2, varscan2
- ABCB5 | c.2043T>G p.I681M (on ENST00000404938 / NM_001163941.2; = p.I236M on NM_178559.6) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as rs751900178, COSV51705183; called by muse, mutect2, varscan2
- ABCC2 | c.4535T>G p.I1512S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64984977; called by muse, mutect2, varscan2
- ABCC4 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV65310494; called by muse, mutect2, varscan2
- ABCD4 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759637495, COSV53991279; called by muse, mutect2, varscan2
- ABCG4 | c.114G>T p.K38N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV56642446; called by muse, mutect2, varscan2
- ABHD18 | c.796T>G p.L266V (on ENST00000398965 / NM_001039717.2; = p.L173V on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV66293315; called by muse, mutect2, varscan2
- ABI3BP | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs373865185; called by muse, mutect2, varscan2
- ABI3BP | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs759720414, COSV52530661; called by muse, mutect2, varscan2
- ABL1 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59327113, COSV59332005; called by muse, mutect2
- AC013489.1 | c.1409A>G p.D470G | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51550390; called by muse, mutect2, varscan2
- AC093827.5 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs771464463, COSV55744964; called by muse, mutect2
- AC244197.3 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as CM149689, COSV61711562; called by muse, mutect2, varscan2
- ACAD11 | c.899C>A p.S300Y | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (1); PolyPhen possibly damaging (0.481); catalogued as rs1347523848, COSV53895502; called by muse, mutect2, varscan2
- ACAT1 | c.1069A>T p.S357C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56186891; called by muse, mutect2, varscan2
- ACSL4 | c.1779G>T p.K593N (on ENST00000340800 / NM_022977.2; = p.K552N on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV61613634; called by muse, mutect2, varscan2
- ACTC1 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.946); catalogued as COSV51757689; called by muse, mutect2, varscan2
- ACTL7B | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs747709934, COSV65926965; called by muse, mutect2, varscan2
- ACVR2A | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV54020019; called by muse, mutect2, varscan2
- ACVR2A | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs1381913043, COSV54018779, COSV54020026; called by muse, mutect2, varscan2
- ADAM2 | c.1654A>C p.K552Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as COSV55859848; called by muse, mutect2, varscan2
- ADAM21 | c.138G>T p.L46F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV50789371, COSV50793851; called by muse, mutect2, varscan2
- ADAM21 | c.403G>T p.V135L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV50789390; called by muse, mutect2, varscan2
- ADAM22 | c.2492G>A p.R831Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55971893; called by mutect2, varscan2
- ADAM23 | c.1519A>C p.N507H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52210023; called by muse, mutect2, varscan2
- ADAM32 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65947854; called by muse, mutect2, varscan2
- ADAMTS17 | c.2222T>C p.V741A | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV51475125; called by muse, mutect2, varscan2
- ADAMTS2 | c.3581G>T p.R1194I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52367710, COSV52392772; called by muse, mutect2, varscan2
- ADAMTS20 | c.4906G>T p.E1636* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as rs754608821, COSV67128739; called by muse, mutect2, varscan2
- ADAMTS3 | c.3581A>G p.N1194S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV54387135; called by muse, mutect2, varscan2
- ADAMTS9 | c.688A>C p.N230H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1256869280, COSV55776826; called by muse, mutect2, varscan2
- ADAMTSL1 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs772381787, COSV52810337; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1616A>G p.E539G | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV54439712; called by muse, mutect2, varscan2
- ADAP2 | c.200A>T p.D67V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58295307; called by muse, mutect2, varscan2
- ADCY10 | c.1820C>A p.S607Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63239035, COSV63245847; called by muse, mutect2, varscan2
- ADCY5 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59193338; called by muse, mutect2, varscan2
- ADCY9 | c.4003G>A p.E1335K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.048); catalogued as rs374081146; called by muse, mutect2, varscan2
- ADGRA1 | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.678); catalogued as rs1192929865, COSV66925109; called by muse, mutect2, varscan2
- ADGRB2 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57071387; called by muse, mutect2, varscan2
- ADGRB3 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV65387066; called by muse, mutect2, varscan2
- ADGRG2 | c.2491G>T p.D831Y (on ENST00000379869 / NM_001079858.3; = p.D828Y on NM_005756.4) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61337970; called by muse, mutect2, varscan2
- ADGRG4 | c.517A>C p.S173R | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.103); catalogued as COSV54951508; called by muse, mutect2
- ADGRG4 | c.6830C>A p.S2277Y | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.345); catalogued as COSV54951513; called by muse, mutect2, varscan2
- ADGRV1 | c.10901T>G p.I3634S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV67980185, COSV67992012; called by muse, mutect2, varscan2
- ADGRV1 | c.12424C>T p.R4142W | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs534226753, COSV67978187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADNP | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV62424720; called by muse, mutect2, varscan2
- ADORA1 | c.555C>A p.F185L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV55141209; called by muse, mutect2, varscan2
- AFF2 | c.419C>A p.S140Y | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60657786; called by muse, mutect2, varscan2
- AFF3 | c.2920C>T p.P974S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV57844481; called by mutect2, varscan2
- AFF3 | c.2294C>A p.S765Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as rs1223172251, COSV57839331; called by muse, mutect2, varscan2
- AGBL4 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748307842, COSV61891203; called by muse, mutect2, varscan2
- AGPAT4 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV57243767; called by muse, mutect2, varscan2
- AGTR1 | c.38G>T p.R13I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV62557520; called by muse, mutect2, varscan2
- AHNAK | c.12134A>G p.D4045G | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs762667961, COSV57206330; called by muse, mutect2, varscan2
- AIP | c.52A>C p.I18L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1394024916, COSV54159930; called by muse, mutect2, varscan2
- AK9 | c.5152C>T p.R1718* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as rs771948940, COSV69849684; called by muse, mutect2, varscan2
- AK9 | c.470G>T p.R157I | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1372254966, COSV99572343; called by muse, mutect2, varscan2
- AKAP13 | c.2068T>C p.S690P | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV63450891; called by muse, mutect2, varscan2
- AKAP3 | c.1533G>T p.E511D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV57414796; called by muse, mutect2, varscan2
- AKAP7 | c.192A>C p.E64D | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV63504840; called by muse, mutect2, varscan2
- AKNA | c.2716C>T p.R906* | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | catalogued as COSV56311516; called by muse, mutect2, varscan2
- AKNAD1 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV62195925; called by muse, mutect2, varscan2
- AKR1C4 | c.240C>A p.F80L | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54122654; called by muse, mutect2, varscan2
- AL645922.1 | c.3393A>C p.K1131N | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV64887223; called by muse, mutect2
- ALDH1A3 | c.1289A>C p.K430T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV60901076; called by muse, mutect2
- ALKBH1 | c.950C>A p.S317* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV53659057; called by muse, mutect2
- ALMS1 | c.6811A>C p.N2271H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52504782; called by muse, mutect2, varscan2
- ALPK1 | c.1881G>T p.E627D | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV51582971; called by muse, mutect2, varscan2
- ALS2CL | c.2369G>T p.G790V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV59670534; called by muse, mutect2, varscan2
- AMER1 | c.216C>A p.F72L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV57656423; called by muse, mutect2, varscan2
- AMTN | c.346T>C p.S116P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59488551; called by muse, mutect2, varscan2
- AMY2A | c.227G>T p.R76I | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70214335; called by muse, mutect2, varscan2
- ANK3 | c.8626C>A p.H2876N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as COSV55047196, COSV55048368; called by muse, mutect2, varscan2
- ANKFY1 | c.3365G>A p.R1122H (on ENST00000341657 / NM_001330063.2; = p.R1123H on NM_016376.5) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58915174; called by muse, mutect2
- ANKRD13C | c.466A>C p.N156H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52029602; called by muse, mutect2, varscan2
- ANKRD34B | c.1364A>G p.N455S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV58613552; called by muse, mutect2
- ANO1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as rs778151682, COSV60281020, COSV60282101; called by muse, mutect2, varscan2
- ANO5 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 26/64 reads (41%) | catalogued as rs768835530, COSV61082177; called by muse, mutect2, varscan2
- ANO8 | c.943A>G p.T315A | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50173743, COSV50173825; called by muse, mutect2, varscan2
- ANOS1 | c.1523A>C p.K508T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99390447; called by muse, mutect2, varscan2
- AOX1 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as rs146370823; called by muse, mutect2, varscan2
- AP1M1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs200460904, COSV52225294; called by muse, mutect2, varscan2
- AP2B1 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as COSV51997672; called by muse, mutect2, varscan2
- APBB1 | c.1415A>C p.K472T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV54973644; called by muse, mutect2, varscan2
- APC | c.6098A>G p.D2033G | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV57331246; called by muse, mutect2
- APC2 | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs373536854; called by mutect2, varscan2
- APH1B | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV56013865; called by muse, mutect2, varscan2
- APLP1 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.154); catalogued as rs763547342, COSV55702120; called by muse, mutect2, varscan2
- APOB | c.7001T>G p.I2334S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV104373507, COSV51927216; called by muse, mutect2, varscan2
- APOB | c.6661A>C p.N2221H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV51927234; called by muse, mutect2, varscan2
- AQP2 | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52229240; called by muse, mutect2
- ARAP1 | c.2782C>T p.R928* (on ENST00000393609 / NM_001040118.2; = p.R683* on NM_015242.4) | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV61989991; called by muse, varscan2
- ARAP2 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766640340, COSV58283042; called by muse, mutect2, varscan2
- ARAP2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs199740529, COSV58285033; called by muse, mutect2, varscan2
- ARC | c.786G>T p.K262N | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV100751660; called by muse, varscan2
- ARHGAP11A | c.2172G>T p.K724N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV55705444; called by mutect2, varscan2
- ARHGAP20 | c.2669C>A p.S890Y | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs371299206, COSV52807977; called by muse, mutect2, varscan2
- ARHGAP25 | c.722G>A p.R241Q (on ENST00000409202 / NM_001007231.3; = p.R233Q on NM_014882.3) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54899950; called by muse, mutect2, varscan2
- ARHGAP31 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV51790087; called by muse, mutect2, varscan2
- ARHGAP32 | c.512G>T p.R171I | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV59844450, COSV59852972; called by muse, mutect2
- ARHGAP6 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57292951; called by muse, mutect2, varscan2
- ARHGEF12 | c.2114G>A p.R705H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs763312257, COSV63103205; called by muse, mutect2, varscan2
- ARID1A | c.5975C>A p.S1992* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV61370542, COSV61371638, COSV61373486; called by muse, varscan2
- ARID1B | c.3999T>G p.Y1333* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as CM121892, COSV51652670; called by muse, mutect2, varscan2
- ARID5B | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV54414410, COSV54415940; called by muse, mutect2, varscan2
- ARL5B | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV66010993; called by muse, mutect2, varscan2
- ARMC4 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs752348839, COSV100536620, COSV59458741; called by muse, mutect2, varscan2
- ARMC5 | c.1190T>G p.F397C | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51655290; called by muse, mutect2, varscan2
- ARMC8 | c.856C>T p.R286* (on ENST00000469044 / NM_001363941.2; = p.R272* on NM_014154.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV61767906; called by muse, mutect2, varscan2
- ARMH4 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as rs767027409, COSV50762458; called by muse, mutect2, varscan2
- ARPP21 | c.1963C>T p.R655W | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375827523; called by muse, mutect2, varscan2
- ARRB1 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs1363127351, COSV63574705; called by muse, mutect2, varscan2
- ART5 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as rs767744521, COSV63364176; called by muse, mutect2, varscan2
- ASB16 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV53234256; called by muse, mutect2
- ASCC3 | c.938T>A p.I313N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs751120994, COSV61226556; called by muse, mutect2, varscan2
- ASH1L | c.6777T>G p.D2259E (on ENST00000368346 / NM_001366177.2; = p.D2254E on NM_018489.3) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV64206274; called by muse, mutect2, varscan2
- ASH1L | c.5169A>C p.Q1723H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV64206278; called by muse, mutect2, varscan2
- ASH1L | c.184A>G p.K62E | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as COSV64206280; called by muse, mutect2, varscan2
- ASIC2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.871); catalogued as COSV63309139; called by muse, mutect2, varscan2
- ASPH | c.892G>T p.V298L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.034); catalogued as COSV62858306; called by muse, mutect2, varscan2
- ASXL2 | c.3472G>A p.A1158T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV55455131; called by muse, mutect2, varscan2
- ASXL3 | c.503G>T p.R168I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52480241, COSV99323470; called by muse, mutect2, varscan2
- ATM | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1196453563, COSV53732018; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10A | c.4035G>T p.K1345N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV63514028, COSV63514794; called by muse, mutect2, varscan2
- ATP10D | c.3922T>C p.S1308P | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99905156; called by muse, mutect2
- ATP11B | c.854C>A p.S285* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV60026939; called by muse, mutect2
- ATP12A | c.2723A>G p.D908G | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV54513463; called by muse, mutect2, varscan2
- ATP13A4 | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1560198214, COSV55067024; called by muse, mutect2, varscan2
- ATP13A5 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV60866921, COSV60867898; called by muse, mutect2, varscan2
- ATP2B1 | c.2091T>G p.C697W | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV53805091; called by muse, mutect2, varscan2
- ATP5MC3 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52976154; called by muse, mutect2, varscan2
- ATP5PD | c.299C>A p.S100Y | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.59); catalogued as COSV56902543; called by muse, mutect2, varscan2
- ATP6AP2 | c.1014T>G p.I338M (on ENST00000378438; = p.I339M on NM_005765.3) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65797350; called by muse, mutect2, varscan2
- ATP6V1B2 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as rs777139485, COSV52352683; called by muse, mutect2, varscan2
- ATP6V1C2 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV55358534; called by muse, mutect2, varscan2
- ATP8B1 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV52173605; called by muse, mutect2, varscan2
- ATP8B2 | c.3164T>A p.F1055Y (on ENST00000672630; = p.F1022Y on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV59245178; called by muse, mutect2, varscan2
- ATRNL1 | c.3575A>C p.E1192A | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV58077763, COSV58085957; called by muse, mutect2, varscan2
- ATXN3L | c.1041G>T p.K347N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66075350; called by muse, mutect2, varscan2
- AUP1 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs755973491, COSV51206410; called by muse, mutect2, varscan2
- AXL | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as rs1176757863, COSV56565136; called by muse, mutect2, varscan2
- AXL | c.2630C>A p.A877D (on ENST00000301178 / NM_021913.5; = p.A868D on NM_001699.6) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.088); catalogued as COSV56565149; called by muse, mutect2, varscan2
- AZI2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201211825, COSV55423349; called by muse, mutect2, varscan2
- B3GALNT2 | c.1479T>G p.D493E | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV64003565; called by muse, mutect2, varscan2
- B4GALT6 | c.481C>A p.L161I | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.74); PolyPhen benign (0.077); catalogued as COSV52702858; called by muse, mutect2, varscan2
- BANK1 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs1213771996, COSV59839801; called by muse, mutect2, varscan2
- BAZ2A | c.1480A>G p.K494E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs780402614, COSV51633198, COSV51636196; called by muse, mutect2, varscan2
- BAZ2B | c.4615T>G p.F1539V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV58597048; called by muse, mutect2, varscan2
- BBS10 | c.1459T>G p.L487V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV67913090; called by muse, mutect2, varscan2
- BBS10 | c.804T>G p.F268L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs770050659, COSV53879505; called by muse, mutect2, varscan2
- BBS12 | c.1657C>A p.L553I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV58561572; called by muse, mutect2
- BCHE | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as rs780411054, COSV52254483; called by muse, mutect2, varscan2
- BEGAIN | c.299A>C p.N100T | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62068211; called by muse, mutect2, varscan2
- BEST2 | c.564C>A p.F188L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV50360082; called by muse, mutect2, varscan2
- BIRC6 | c.6219G>T p.K2073N | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV70196676; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3198G>T p.E1066D | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV63244296; called by muse, mutect2, varscan2
- BLMH | c.800A>C p.K267T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99913006; called by muse, mutect2
- BLNK | c.1164C>A p.F388L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.862); catalogued as rs1554894851, COSV56409533; called by muse, mutect2, varscan2
- BMP5 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.333); catalogued as rs144615410; called by muse, mutect2, varscan2
- BMPR2 | c.1036A>G p.T346A | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV65807993; called by muse, mutect2, varscan2
- BNC2 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66142280; called by muse, mutect2, varscan2
- BPTF | c.4291G>T p.D1431Y | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.44); catalogued as COSV58833090; called by muse, mutect2
- BRCA2 | c.2451G>T p.K817N | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs767686668, COSV66451277; ClinVar: uncertain significance; called by mutect2, varscan2
- BRD9 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 5/67 reads (7%) | catalogued as COSV100056851; called by muse, mutect2
- BRIP1 | c.379+2T>G p.X127_splice | Splice Site (SNP) | VAF 17/47 reads (36%) | catalogued as COSV51995811; called by muse, mutect2, varscan2
- BRSK2 | c.268T>G p.Y90D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.598); catalogued as COSV57541019; called by muse, mutect2, varscan2
- BSN | c.7016A>G p.D2339G | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1159641320, COSV56514216; called by muse, mutect2, varscan2
- BSND | c.171C>A p.Y57* | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | catalogued as COSV64870389; called by muse, mutect2, varscan2
- C12orf4 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs532268400, COSV54205508; called by muse, mutect2, varscan2
- C12orf45 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs748939881, COSV55012518; called by muse, mutect2, varscan2
- C12orf66 | c.426C>A p.F142L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.044); catalogued as COSV61322602; called by muse, mutect2, varscan2
- C19orf57 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60967424; called by muse, mutect2, varscan2
- C1GALT1C1 | c.64A>G p.I22V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV58973855; called by muse, mutect2, varscan2
- C1QTNF1 | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV59261065; called by muse, mutect2, varscan2
- C20orf96 | c.792G>T p.K264N (on ENST00000360321 / NM_153269.3; = p.K263N on NM_080571.1) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV64403205; called by muse, mutect2
- C2CD5 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV61723360; called by muse, mutect2, varscan2
- C2orf73 | c.683C>A p.S228Y | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58310262; called by muse, mutect2, varscan2
- C3orf14 | c.41G>T p.R14I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1012496690, COSV51706445, COSV51707350; called by muse, mutect2, varscan2
- C4orf51 | c.245C>A p.T82K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV71263886; called by muse, varscan2
- C5orf38 | c.410G>T p.R137I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs779809202, COSV57409721; called by muse, mutect2, varscan2
- C6 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.411); catalogued as rs763257632, COSV54704717; called by muse, mutect2
- C6orf118 | c.1141A>C p.I381L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV57813388; called by muse, mutect2, varscan2
- C7orf57 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375449810; called by muse, mutect2, varscan2
- C8orf34 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs771361055, COSV57397940; called by muse, mutect2, varscan2
- C9orf43 | c.14A>C p.D5A | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55912063; called by muse, mutect2, varscan2
- CA4 | c.197A>C p.K66T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV56281063; called by muse, mutect2, varscan2
- CACHD1 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV51549876; called by muse, mutect2, varscan2
- CACHD1 | c.2693T>C p.V898A | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV51549888; called by muse, mutect2, varscan2
- CACNA1A | c.3725A>G p.Y1242C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100800972; called by muse, mutect2
- CACNA1B | c.5077T>G p.F1693V | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53117518; called by muse, mutect2, varscan2
- CACNA1D | c.5251C>T p.P1751S (on ENST00000350061 / NM_001128840.3; = p.P1771S on NM_000720.4) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV55440503; called by muse, mutect2, varscan2
- CACNA1S | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs757755172, COSV62937278; called by muse, mutect2, varscan2
- CACNA2D1 | c.1237A>C p.I413L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV62375016; called by muse, mutect2, varscan2
- CADPS | c.3124A>C p.M1042L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.354); catalogued as COSV51871087; called by muse, mutect2, varscan2
- CALHM5 | c.31T>G p.F11V | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV62067422; called by muse, mutect2, varscan2
- CAMK1D | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs752176853, COSV66606593; called by muse, mutect2, varscan2
- CAMK4 | c.838T>G p.L280V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56664867; called by muse, mutect2, varscan2
- CAND1 | c.1339A>C p.S447R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV73389552; called by muse, mutect2
- CANX | c.249G>A p.W83* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV56003051; called by muse, mutect2, varscan2
- CAPZA2 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 26/49 reads (53%) | catalogued as COSV63266083; called by muse, mutect2, varscan2
- CARD11 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV62754406; called by muse, mutect2, varscan2
- CARMIL2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.706); catalogued as rs948490082, COSV58024112; called by muse, mutect2, varscan2
- CARMIL2 | c.3189C>A p.F1063L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV54666393; called by muse, mutect2, varscan2
- CARMIL3 | c.526C>A p.Q176K | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV57725372; called by muse, mutect2, varscan2
- CASD1 | c.1615A>C p.I539L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV51971124; called by muse, mutect2, varscan2
- CASKIN2 | c.2941G>A p.D981N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs200351544, COSV58593577, COSV58598073; called by muse, mutect2, varscan2
- CASP14 | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.353); catalogued as COSV55664986; called by muse, mutect2, varscan2
- CASP6 | c.296A>C p.K99T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.111); catalogued as COSV54460401; called by muse, mutect2, varscan2
- CASP8AP2 | c.590A>C p.N197T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV52745692; called by muse, mutect2, varscan2
- CATSPER4 | c.905T>C p.F302S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.39); catalogued as COSV58792526; called by muse, mutect2, varscan2
- CATSPERE | c.323T>G p.V108G | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV63676675; called by muse, mutect2, varscan2
- CATSPERE | c.1885A>C p.K629Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV63676682; called by muse, mutect2
- CBLL2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.121); catalogued as rs865948991, COSV60368562; called by muse, mutect2, varscan2
- CBX3 | c.185A>C p.E62A | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV61761258; called by muse, mutect2, varscan2
- CCDC116 | c.708G>T p.E236D | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV53037283; called by muse, mutect2, varscan2
- CCDC142 | c.665A>C p.H222P | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51776533; called by muse, mutect2
- CCDC160 | c.599A>G p.D200G | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV66251391; called by muse, mutect2, varscan2
- CCDC170 | c.1912A>C p.K638Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.108); catalogued as COSV53337856; called by muse, mutect2, varscan2
- CCDC171 | c.1838A>G p.D613G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1564296094, COSV52635604; called by muse, mutect2
- CCDC174 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.047); catalogued as COSV57980390; called by muse, mutect2, varscan2
- CCDC181 | c.76T>G p.L26V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV63155909; called by muse, mutect2, varscan2
- CCDC38 | c.335T>G p.F112C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60182504; called by mutect2, varscan2
- CCDC47 | c.72T>G p.D24E | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV56722281; called by muse, mutect2, varscan2
- CCDC62 | c.358A>C p.K120Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV53431250; called by muse, mutect2, varscan2
- CCDC74B | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs150161484; called by muse, mutect2, varscan2
- CCDC81 | c.1324A>C p.N442H (on ENST00000445632 / NM_001156474.2; = p.N352H on NM_021827.4) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV53577197; called by muse, mutect2, varscan2
- CCDC9B | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as COSV66874933; called by muse, varscan2
- CCL17 | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as rs369547686; called by muse, mutect2, varscan2
- CCL22 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs146388634; called by muse, mutect2, varscan2
- CCNA1 | c.280A>T p.R94W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV55220404; called by muse, mutect2, varscan2
- CCNA2 | c.1242A>C p.K414N | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV54665202; called by muse, mutect2, varscan2
- CCNB1IP1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs1385967366, COSV100738498; called by muse, mutect2, varscan2
- CCNF | c.1440C>A p.F480L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.251); catalogued as COSV53538323; called by muse, mutect2, varscan2
- CD109 | c.2076G>T p.E692D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54646534; called by muse, mutect2, varscan2
- CD14 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.03); catalogued as COSV57370021; called by muse, mutect2, varscan2
- CD163 | c.2909T>G p.L970R | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63136170; called by muse, mutect2
- CD180 | c.1922T>C p.L641S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.041); catalogued as COSV56517183; called by muse, mutect2, varscan2
- CD200R1L | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as rs1351213746, COSV68003930, COSV68004269; called by muse, mutect2, varscan2
- CD22 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.033); catalogued as rs763054158, COSV50050193, COSV50058335; called by muse, mutect2, varscan2
- CD274 | c.840G>T p.K280N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV67501096; called by muse, varscan2
- CD300A | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as COSV60409666; called by muse, mutect2, varscan2
- CD40LG | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV65698248; called by muse, mutect2, varscan2
- CD5 | c.98T>C p.F33S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as COSV61717990; called by muse, varscan2
- CD63 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV57676066; called by muse, mutect2, varscan2
- CDC16 | c.848-1G>T p.X283_splice | Splice Site (SNP) | VAF 17/50 reads (34%) | catalogued as COSV52958505; called by muse, mutect2, varscan2
- CDC42BPA | c.994A>C p.N332H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV62004973; called by muse, mutect2, varscan2
- CDC45 | c.655T>C p.W219R | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54244084; called by muse, mutect2, varscan2
- CDCA7L | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | catalogued as rs763777079, COSV60944686; called by muse, mutect2, varscan2
- CDCP1 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.469); catalogued as rs370335828; called by muse, mutect2, varscan2
- CDH10 | c.2164G>T p.D722Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100051840, COSV52573615; called by muse, mutect2, varscan2
- CDH10 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.153); catalogued as COSV52573625; called by muse, mutect2, varscan2
- CDH12 | c.232-1G>A p.X78_splice | Splice Site (SNP) | VAF 37/127 reads (29%) | catalogued as COSV66393079; called by muse, mutect2, varscan2
- CDH19 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV50955341; called by muse, mutect2, varscan2
- CDH23 | c.1868T>G p.V623G | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as COSV54927036; called by muse, mutect2, varscan2
- CDK17 | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV54127319, COSV99703093; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2414G>A p.G805E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62572755, COSV62578333; called by muse, mutect2, varscan2
- CDKL2 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV56732526; called by muse, mutect2, varscan2
- CDON | c.3265C>A p.H1089N | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV54995922, COSV54998889; called by muse, mutect2, varscan2
- CECR2 | c.2341C>T p.R781* (on ENST00000342247 / NM_001290047.2; = p.R598* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV52837713; called by muse, mutect2, varscan2
- CENPF | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV65273272; called by muse, mutect2, varscan2
- CENPF | c.8533G>T p.E2845* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as COSV65273276; called by muse, mutect2, varscan2
- CENPO | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs574000727, COSV53229527; called by muse, mutect2, varscan2
- CENPU | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55656771, COSV55657004; called by muse, mutect2, varscan2
- CEP162 | c.3951G>T p.K1317N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as COSV100003320, COSV57618196; called by muse, mutect2, varscan2
- CEP192 | c.4786C>A p.L1596I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV58061140, COSV58062792; called by muse, mutect2, varscan2
- CEP290 | c.138A>C p.E46D | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV57122716; called by muse, mutect2, varscan2
- CEP76 | c.1301A>C p.K434T | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV50865789; called by muse, mutect2
- CEP97 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as rs767173679, COSV59123277; called by muse, mutect2, varscan2
- CERKL | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV59213217; called by muse, varscan2
- CFAP46 | c.7233C>A p.D2411E | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV99583979, COSV99585329; called by muse, mutect2, varscan2
- CFAP47 | c.4456T>G p.L1486V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.436); catalogued as COSV57971980; called by muse, mutect2
- CFAP47 | c.5118G>T p.Q1706H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57971985; called by mutect2, varscan2
- CFAP54 | c.6574A>G p.T2192A | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.03); catalogued as COSV61571116; called by muse, mutect2, varscan2
- CFAP54 | c.6769A>C p.K2257Q | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as COSV61571120; called by muse, mutect2
- CFAP69 | c.2257G>T p.D753Y | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60184661; called by muse, mutect2, varscan2
- CFAP97 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs373566490, COSV57109285; called by muse, mutect2, varscan2
- CHAF1A | c.99A>G p.I33M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV56670803; called by muse, mutect2, varscan2
- CHD1L | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782711426, COSV63613096; called by muse, mutect2, varscan2
- CHD3 | c.3760C>A p.H1254N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57873196; called by muse, mutect2, varscan2
- CHI3L1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs746382181, COSV55137359; called by muse, mutect2, varscan2
- CHID1 | c.557T>C p.F186S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60258129; called by muse, mutect2, varscan2
- CHM | c.677G>T p.R226I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63300456; called by muse, mutect2, varscan2
- CHN1 | c.685C>A p.L229I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV55032440; called by muse, mutect2, varscan2
- CHRM2 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.173); catalogued as rs1447700613, COSV57767559; called by muse, mutect2, varscan2
- CIB4 | c.74G>T p.R25I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV56599662; called by muse, mutect2, varscan2
- CILP | c.1026T>G p.F342L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV56022583; called by muse, mutect2, varscan2
- CIT | c.5150A>C p.E1717A | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as COSV55862858; called by muse, mutect2, varscan2
- CLCA4 | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV55366940, COSV55369585; called by muse, mutect2, varscan2
- CLCN6 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV56738519; called by muse, mutect2, varscan2
- CLHC1 | c.1574A>G p.E525G | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV68463709; called by muse, mutect2, varscan2
- CLIP3 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs370765485; called by muse, mutect2, varscan2
- CLK1 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs758189196, COSV58432571; called by muse, mutect2, varscan2
- CLK3 | c.1828A>G p.T610A (on ENST00000395066 / NM_001130028.1; = p.T462A on NM_003992.4) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV100165772; called by muse, mutect2, varscan2
- CLUL1 | c.1196T>G p.F399C | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58111522; called by muse, mutect2, varscan2
- CMTM2 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778788831, COSV51748146; called by muse, mutect2, varscan2
- CMTR1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV65089699; called by muse, varscan2
- CMTR1 | c.2052G>T p.E684D | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV65089704; called by muse, mutect2, varscan2
- CMYA5 | c.4833A>T p.Q1611H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV71404481; called by muse, mutect2, varscan2
- CNGA2 | c.1728G>T p.E576D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV61703633; called by muse, mutect2, varscan2
- CNIH3 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.686); catalogued as rs529360966, COSV55273475; called by muse, mutect2, varscan2
- CNKSR2 | c.1851C>A p.F617L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV54251153; called by muse, mutect2, varscan2
- CNOT10 | c.1676T>G p.L559R | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59390987; called by muse, mutect2, varscan2
- CNOT6 | c.1244C>A p.S415Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56159657; called by muse, mutect2, varscan2
- CNTF | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV60157826; called by muse, mutect2
- CNTNAP4 | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56669263; called by muse, mutect2, varscan2
- COCH | c.1786G>T p.E596* (on ENST00000216361 / NM_001347720.1; = p.E531* on NM_004086.3) | Nonsense Mutation (SNP) | VAF 21/39 reads (54%) | catalogued as COSV53549978; called by muse, mutect2, varscan2
- COG1 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV55427938; called by muse, mutect2, varscan2
- COL11A1 | c.4779G>T p.M1593I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV62175697, COSV62177733; called by muse, mutect2, varscan2
- COL13A1 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.054); catalogued as rs755589502, COSV62567829; called by muse, mutect2, varscan2
- COL19A1 | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.934); catalogued as COSV59567928; called by muse, mutect2, varscan2
- COL22A1 | c.3850T>G p.S1284A | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57327865; called by muse, mutect2, varscan2
- COL24A1 | c.2092C>A p.P698T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV65303298; called by muse, mutect2, varscan2
- COL25A1 | c.1515G>A p.P505= | Splice Region (SNP) | VAF 31/59 reads (53%) | catalogued as rs371922822; called by muse, mutect2, varscan2
- COL2A1 | c.3545G>A p.G1182D | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CM126450, COSV61528694; called by muse, mutect2, varscan2
- COL4A1 | c.4924T>C p.F1642L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101010966; called by muse, mutect2
- COL4A2 | c.4114C>T p.P1372S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV64625923; called by muse, mutect2
- COL4A6 | c.1648C>A p.L550I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV57860901; called by muse, mutect2, varscan2
- COL6A3 | c.3034C>A p.L1012I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.795); catalogued as COSV55082675, COSV55100046; called by muse, mutect2, varscan2
- COL6A6 | c.2192A>G p.D731G | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62019855; called by muse, mutect2, varscan2
- CORIN | c.2507A>C p.K836T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV56687909; called by muse, mutect2, varscan2
- CORIN | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs755588946, COSV56687921, COSV99903902; called by muse, mutect2, varscan2
- CPLX4 | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV55312747, COSV55313119, COSV55313627; called by muse, mutect2, varscan2
- CPO | c.322C>A p.H108N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55938961; called by muse, mutect2, varscan2
- CPQ | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as COSV55139966; called by muse, mutect2, varscan2
- CPSF4 | c.49A>G p.I17V | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV52856739; called by muse, mutect2, varscan2
- CR1 | c.4465C>T p.R1489* | Nonsense Mutation (SNP) | VAF 47/109 reads (43%) | catalogued as rs778591697, COSV65456307; called by muse, mutect2, varscan2
- CRACD | c.3583G>T p.E1195* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV51717073, COSV99948470; called by muse, mutect2, varscan2
- CRB2 | c.2459G>T p.G820V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100749527; called by muse, mutect2, varscan2
- CREBBP | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52114930; called by muse, mutect2
- CRISP2 | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs751942950, COSV59253346; called by muse, mutect2, varscan2
- CROT | c.1025T>C p.V342A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV58973166; called by muse, mutect2, varscan2
- CSF3R | c.1121C>A p.S374Y | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV58964310; called by muse, mutect2, varscan2
- CSMD1 | c.6067G>A p.E2023K (on ENST00000520002; = p.E2022K on NM_033225.6) | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746245674, COSV59294475; called by muse, mutect2, varscan2
- CSMD1 | c.256T>G p.L86V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV68178204; called by muse, mutect2
- CSMD3 | c.3159C>A p.N1053K (on ENST00000297405 / NM_001363185.1; = p.N949K on NM_052900.3) | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); catalogued as rs1005865709, COSV52125496; called by muse, mutect2, varscan2
- CSPG4 | c.5360C>T p.A1787V | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1346446991, COSV57891911; called by muse, mutect2, varscan2
- CSPG4 | c.923C>A p.S308* | Nonsense Mutation (SNP) | VAF 35/103 reads (34%) | catalogued as COSV57891927, COSV57900762; called by muse, mutect2, varscan2
- CT83 | c.248A>C p.N83T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV64140836; called by muse, mutect2, varscan2
- CTAGE1 | c.1507T>C p.S503P | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV66943054; called by muse, mutect2, varscan2
- CTCF | c.1891G>T p.E631* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV50462752; called by muse, mutect2, varscan2
- CTH | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866702899, COSV61007353, COSV61007832; called by muse, mutect2
- CTR9 | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761302085, COSV63728050; called by muse, mutect2, varscan2
- CTSO | c.877A>C p.S293R | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.076); catalogued as COSV70808893, COSV70809027; called by muse, mutect2
- CUBN | c.7188G>T p.E2396D | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs781074289, COSV64709984, COSV64721968; called by muse, mutect2, varscan2
- CUZD1 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 19/64 reads (30%) | catalogued as rs142209822; called by muse, mutect2, varscan2
- CWC25 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs775047995; called by muse, mutect2, varscan2
- CWH43 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV56936914; called by muse, mutect2, varscan2
- CYP19A1 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV53059112; called by muse, mutect2, varscan2
- CYP1A1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.072); catalogued as rs1450069713, COSV65696673; called by muse, mutect2, varscan2
- CYP24A1 | c.512A>C p.E171A | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.772); catalogued as COSV99398039; called by muse, mutect2
- CYP26A1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56416825; called by muse, mutect2
- CYP27A1 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.354); catalogued as rs1193291074, COSV51467320; called by mutect2, varscan2
- CYP4X1 | c.160T>C p.F54L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV64149911; called by muse, mutect2, varscan2
- DACH1 | c.1534C>T p.R512C (on ENST00000619232 / NM_001366712.1; = p.R460C on NM_080759.6) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as rs1360283264, COSV57492480; called by mutect2, varscan2
- DAOA | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs757009026, COSV100298829, COSV61601843; called by mutect2, varscan2
- DCAF12L2 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV63580722, COSV63582449, COSV63583358; called by muse, mutect2, varscan2
- DCC | c.2053+2T>G p.X685_splice | Splice Site (SNP) | VAF 6/11 reads (55%) | catalogued as COSV59090338; called by muse, mutect2
- DCHS1 | c.7828A>G p.T2610A | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54996473; called by muse, mutect2, varscan2
- DCST2 | c.1739G>A p.S580N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.035); catalogued as COSV55050581; called by muse, mutect2, varscan2
- DCTN6 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as COSV55317209; called by muse, mutect2, varscan2
- DCUN1D2 | c.356G>T p.R119I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV100215077, COSV100215145, COSV60261272; called by muse, mutect2, varscan2
- DCUN1D3 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs142074017, COSV60952713, COSV60953641; called by muse, mutect2, varscan2
- DDB2 | c.807T>G p.I269M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.732); catalogued as COSV57037445; called by muse, mutect2
- DDX28 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV60105625; called by muse, mutect2, varscan2
- DDX60 | c.4336G>T p.E1446* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV67095545; called by muse, mutect2, varscan2
- DENND4A | c.3944A>C p.K1315T | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV101475263; called by muse, mutect2
- DENND4C | c.1598A>C p.K533T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.471); catalogued as COSV66821639; called by muse, mutect2, varscan2
- DEPDC5 | c.3743T>C p.V1248A (on ENST00000400246; = p.V1317A on NM_014662.5) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.755); catalogued as COSV56692824; called by muse, mutect2, varscan2
- DGKB | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99336557; called by muse, mutect2, varscan2
- DGKK | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV65706692; called by muse, mutect2, varscan2
- DHDH | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as rs1158666356, COSV55481662; called by muse, mutect2, varscan2
- DHRS7B | c.901C>G p.R301G | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60887415; called by muse, mutect2, varscan2
- DHX9 | c.972A>C p.Q324H | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV62358615; called by muse, mutect2, varscan2
- DICER1 | c.440T>C p.V147A | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58616689; called by muse, mutect2
- DISP3 | c.203T>C p.F68S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as rs1167312493, COSV53822491; called by muse, mutect2, varscan2
- DKK1 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 30/56 reads (54%) | catalogued as COSV64760035; called by muse, mutect2, varscan2
- DLAT | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV54769494; called by muse, mutect2
- DLG2 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV54628183; called by muse, mutect2, varscan2
- DLG2 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); catalogued as rs150043290, COSV65834644; called by muse, mutect2, varscan2
- DMD | c.10172G>A p.R3391Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1423537877, COSV58896676; called by muse, mutect2, varscan2
- DMD | c.8749A>C p.K2917Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as COSV58896707; called by muse, mutect2, varscan2
- DMD | c.6630G>T p.K2210N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as COSV58896731; called by muse, mutect2, varscan2
- DMXL1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs147324580; called by muse, mutect2, varscan2
- DNA2 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV64427789; called by muse, mutect2, varscan2
- DNAH11 | c.4640A>G p.E1547G | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60944719; called by muse, mutect2, varscan2
- DNAH11 | c.4807T>G p.L1603V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as COSV60944739; called by muse, mutect2, varscan2
- DNAH11 | c.11426G>T p.R3809L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV60944762, COSV60945057; called by muse, varscan2
- DNAH2 | c.4563T>G p.D1521E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.735); catalogued as COSV66717476; called by muse, mutect2, varscan2
- DNAH3 | c.8457C>T p.S2819= | Splice Region (SNP) | VAF 14/44 reads (32%) | catalogued as rs754426138, COSV54509182; called by muse, mutect2, varscan2
- DNAH3 | c.3084+1G>A p.X1028_splice | Splice Site (SNP) | VAF 12/40 reads (30%) | catalogued as COSV54509202; called by muse, mutect2, varscan2
- DNAH7 | c.11282C>A p.P3761Q | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56755569, COSV56791911; called by muse, mutect2, varscan2
- DNAH8 | c.1110G>T p.E370D | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.055); catalogued as COSV59431368, COSV59459761; called by muse, mutect2, varscan2
- DNAH8 | c.4915dup p.I1639Nfs*5 | Frame Shift Ins (INS) | VAF 4/12 reads (33%) | catalogued as rs1202415381; called by mutect2, varscan2
- DNAH8 | c.5890A>C p.K1964Q | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59431385; called by muse, mutect2
- DNAH8 | c.9310G>A p.E3104K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs200884766, COSV59426129; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.10453G>T p.E3485* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100546658, COSV59431405; called by muse, mutect2, varscan2
- DNAH9 | c.8233G>T p.D2745Y | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV52339394; called by muse, mutect2, varscan2
- DNAI2 | c.383A>C p.D128A | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV56757378; called by muse, mutect2, varscan2
- DNAI2 | c.1070T>G p.V357G | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.176); catalogued as COSV56757392; called by muse, mutect2, varscan2
- DNAJC21 | c.1090A>C p.N364H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57759534; called by muse, mutect2
- DNAJC6 | c.212C>A p.S71Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54771356; called by muse, mutect2, varscan2
- DNAJC6 | c.2673G>T p.K891N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54771374; called by muse, mutect2, varscan2
- DNMT1 | c.1904A>C p.Q635P | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV61577269; called by muse, mutect2, varscan2
- DOCK1 | c.438G>T p.K146N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54732954; called by muse, mutect2, varscan2
- DOCK10 | c.3895A>G p.T1299A | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.03); catalogued as COSV51357524; called by muse, mutect2, varscan2
- DOCK11 | c.5243A>C p.K1748T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52235149; called by muse, mutect2, varscan2
- DOCK2 | c.3503C>T p.A1168V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV56946909; called by muse, mutect2, varscan2
- DOCK2 | c.3914C>T p.A1305V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs370316549; called by muse, mutect2, varscan2
- DOCK3 | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56508684; called by muse, mutect2, varscan2
- DOCK5 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV52397486; called by muse, mutect2, varscan2
- DOCK5 | c.3370A>G p.T1124A | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV52397495; called by muse, mutect2, varscan2
- DOCK5 | c.3467A>G p.D1156G | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52397509; called by mutect2, varscan2
- DOCK8 | c.3630A>C p.K1210N | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV66618565; called by muse, mutect2, varscan2
- DOP1A | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); catalogued as rs777038498, COSV52707804; called by muse, varscan2
- DOP1B | c.5348C>A p.S1783Y | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV67692462; called by muse, mutect2, varscan2
- DOP1B | c.6656G>A p.S2219N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1182583536, COSV67690694; called by muse, mutect2, varscan2
- DPP4 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV62105643; called by muse, mutect2
- DPRX | c.125A>C p.N42T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.017); catalogued as COSV64949296; called by muse, mutect2, varscan2
- DPY19L2 | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.024); catalogued as COSV60541895; called by muse, mutect2, varscan2
- DPYS | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV60907185; called by muse, mutect2, varscan2
- DRC3 | c.1330T>C p.F444L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.079); catalogued as COSV58262081; called by muse, mutect2, varscan2
- DRP2 | c.2243G>T p.S748I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65809543; called by muse, mutect2, varscan2
- DSC2 | c.620A>C p.E207A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.314); catalogued as COSV51862179; called by muse, mutect2, varscan2
- DSEL | c.2927C>A p.S976Y | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.394); catalogued as rs1482285500, COSV59489979; called by muse, mutect2, varscan2
- DSEL | c.2417C>A p.S806Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.793); catalogued as COSV59489992; called by muse, mutect2, varscan2
- DSG3 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57124818, COSV57126464; called by muse, mutect2, varscan2
- DST | c.18640G>T p.E6214* (on ENST00000361203 / NM_001374722.1; = p.E3911* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV55002317; called by muse, mutect2, varscan2
- DTWD1 | c.53A>C p.K18T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); catalogued as COSV52071236; called by muse, mutect2, varscan2
- DTX4 | c.1404G>T p.K468N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57089147; called by mutect2, varscan2
- DUOX1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs879029084, COSV50993197, COSV50994094; called by muse, mutect2, varscan2
- DUSP12 | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63411208; called by muse, mutect2, varscan2
- DYNC1H1 | c.6414A>G p.I2138M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV64134981; called by muse, mutect2, varscan2
- DYNC2H1 | c.1503G>T p.K501N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV62088926; called by muse, mutect2, varscan2
- DYNC2I1 | c.59A>C p.K20T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV68103943; called by muse, mutect2, varscan2
- DYSF | c.3882G>T p.E1294D | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV50277955; called by muse, mutect2, varscan2
- DZIP3 | c.1009T>G p.L337V | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV64311399; called by muse, mutect2, varscan2
- DZIP3 | c.2917G>T p.E973* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV64311402; called by mutect2, varscan2
- EBF3 | c.1048G>T p.E350* (on ENST00000355311 / NM_001375392.1; = p.E341* on NM_001005463.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV62472936, COSV62473660; called by muse, mutect2, varscan2
- ECT2 | c.84G>T p.E28D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.986); catalogued as COSV51687028; called by muse, mutect2, varscan2
- EDAR | c.473A>C p.N158T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV51500629; called by muse, mutect2, varscan2
- EFCAB5 | c.904G>T p.G302* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV57927047; called by muse, mutect2, varscan2
- EFHB | c.2112G>T p.E704D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV55545648; called by muse, mutect2, varscan2
- EHBP1 | c.1404T>G p.F468L | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as COSV99860085; called by muse, mutect2
- EI24 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as rs1477844259, COSV54019064; called by muse, mutect2, varscan2
- EIF3A | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs772554138, COSV64960718; called by muse, mutect2, varscan2
- EIF4G1 | c.2921G>A p.R974H (on ENST00000346169 / NM_198241.3; = p.R779H on NM_004953.5) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV59989669; called by muse, mutect2, varscan2
- ELAVL2 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as rs758305724, COSV56359050; called by muse, mutect2, varscan2
- ELF1 | c.1397T>G p.F466C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53497612; called by muse, mutect2, varscan2
- EMILIN2 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs546388595, COSV54420420; called by muse, mutect2
- ENPP2 | c.2544A>C p.E848D (on ENST00000075322 / NM_001040092.3; = p.E900D on NM_006209.5) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV50010886; called by muse, mutect2, varscan2
- ENPP2 | c.1400G>A p.G467E (on ENST00000075322 / NM_001040092.3; = p.G519E on NM_006209.5) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as rs567059238, COSV50010911; called by muse, mutect2, varscan2
- ENTPD3 | c.590T>G p.F197C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57193631; called by muse, mutect2, varscan2
- EPB41L1 | c.2596G>T p.E866* | Nonsense Mutation (SNP) | VAF 24/43 reads (56%) | catalogued as COSV52434988; called by muse, mutect2, varscan2
- EPS8L3 | c.1164C>A p.F388L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.382); catalogued as COSV62608936; called by muse, mutect2, varscan2
- EPYC | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV53798864, COSV53800722; called by muse, mutect2, varscan2
- ERBB4 | c.2008A>G p.T670A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.053); catalogued as COSV53511045; called by muse, mutect2, varscan2
- ERCC6 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs768589918, COSV63388430; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERCC6L | c.2535A>C p.K845N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV57819772; called by muse, mutect2, varscan2
- ERCC6L | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339227994, COSV57819781; called by muse, mutect2, varscan2
- ERG | c.749G>T p.R250I (on ENST00000398919 / NM_001243428.1; = p.R243I on NM_182918.4) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV55728457; called by muse, mutect2, varscan2
- ERGIC1 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67126882; called by muse, mutect2, varscan2
- ERRFI1 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as rs781338553, COSV66310438; called by muse, mutect2, varscan2
- ESCO2 | c.125A>C p.K42T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV59413572; called by muse, mutect2
- ESRP1 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as COSV64409346, COSV64412577; called by muse, mutect2, varscan2
- ETNPPL | c.1270T>C p.F424L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV56594904; called by muse, mutect2, varscan2
- EXOC4 | c.2622T>G p.I874M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV54087773; called by muse, mutect2, varscan2
- EYA1 | c.1624A>C p.I542L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as COSV58158451; called by muse, mutect2, varscan2
- EYA3 | c.292A>C p.T98P | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV65815786; called by muse, mutect2, varscan2
- EZR | c.1281G>T p.K427N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV51908691; called by muse, mutect2, varscan2
- F13A1 | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs201444282, COSV53554345; called by muse, mutect2, varscan2
- F13B | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.186); catalogued as rs767986906, COSV66372731; called by muse, mutect2, varscan2
- F5 | c.6401C>T p.T2134M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199601865; called by muse, mutect2, varscan2
- F5 | c.2518C>A p.L840I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as rs747488880, COSV63121837; called by muse, mutect2, varscan2
- F5 | c.2068G>T p.E690* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV63121841, COSV63124258; called by muse, mutect2, varscan2
- F8 | c.5068G>T p.E1690* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV64270481; called by muse, mutect2, varscan2
- FABP4 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56268721; called by muse, mutect2, varscan2
- FAH | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777899653, COSV55720503; called by muse, mutect2, varscan2
- FAHD2A | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV99271876; called by muse, mutect2
- FAM133A | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.752); catalogued as COSV59074150; called by muse, mutect2, varscan2
- FAM135B | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752489635, COSV50521991, COSV50523965; called by muse, mutect2, varscan2
- FAM151B | c.389T>G p.I130S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV99971589; called by muse, mutect2
- FAM193B | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as rs940695682, COSV61557494; called by muse, mutect2, varscan2
- FAM214A | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs376021732, COSV55922738; called by muse, mutect2, varscan2
- FAM234B | c.1864-1G>T p.X622_splice | Splice Site (SNP) | VAF 8/16 reads (50%) | catalogued as COSV52193411; called by muse, mutect2, varscan2
- FAM47C | c.2883G>T p.K961N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.366); catalogued as COSV100792280, COSV63730284; called by muse, mutect2
- FAM50A | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.378); catalogued as COSV50130827; called by muse, mutect2, varscan2
- FAM83B | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1405407415, COSV60920130; called by muse, mutect2, varscan2
- FAN1 | c.697G>T p.G233* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV62949836, COSV62949934; called by muse, mutect2, varscan2
- FAR1 | c.899T>G p.I300S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV100701501; called by mutect2, varscan2
- FASTKD3 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV52942245; called by muse, mutect2, varscan2
- FAT4 | c.12881G>A p.R4294K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.937); catalogued as COSV58675253; called by muse, mutect2, varscan2
- FBN3 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs141919495, COSV99561056; called by muse, mutect2, varscan2
- FBXO11 | c.1098T>G p.I366M (on ENST00000403359 / NM_001190274.2; = p.I282M on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.9); catalogued as COSV100319034; called by muse, mutect2
- FBXO34 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs751315141, COSV58253719; called by muse, mutect2, varscan2
- FBXO34 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV58253727; called by muse, mutect2, varscan2
- FBXO39 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs558767788, COSV58621218; called by muse, mutect2, varscan2
- FBXO46 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs372194078; called by muse, mutect2, varscan2
- FBXO5 | c.1086C>A p.F362L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57670515; called by muse, mutect2, varscan2
- FBXW11 | c.816T>G p.C272W | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51606280; called by muse, mutect2, varscan2
- FCHSD1 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs768710494, COSV51836784; called by muse, mutect2, varscan2
- FEM1B | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.134); catalogued as rs775266107, COSV60988027; called by muse, mutect2, varscan2
- FER | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV55285341; called by muse, mutect2
- FERMT2 | c.1095T>G p.I365M | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.653); catalogued as COSV58405693; called by muse, mutect2, varscan2
- FGF5 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV56889780; called by muse, mutect2, varscan2
- FHOD1 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs771435032, COSV50759208; called by muse, mutect2, varscan2
- FILIP1L | c.3272G>A p.R1091Q (on ENST00000354552 / NM_182909.3; = p.R851Q on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs377075355, COSV58765934, COSV58772257; called by muse, mutect2, varscan2
- FLG2 | c.3860G>A p.R1287K | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.087); catalogued as COSV66167216; called by muse, mutect2, varscan2
- FLG2 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs747766822, COSV66167219; called by muse, mutect2, varscan2
- FLT4 | c.924T>G p.Y308* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV56101403; called by muse, mutect2, varscan2
- FN1 | c.6449T>C p.V2150A (on ENST00000359671 / NM_001365524.2; = p.V2119A on NM_002026.4) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60548294; called by muse, mutect2
- FNDC11 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs757814732, COSV64442542; called by muse, mutect2, varscan2
- FOCAD | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV58095158; called by muse, mutect2, varscan2
- FOXJ2 | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV50817633; called by muse, mutect2, varscan2
- FOXQ1 | c.373A>C p.I125L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV57258647; called by muse, mutect2
- FRAT1 | c.835A>C p.S279R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV64017403; called by muse, mutect2, varscan2
- FREM2 | c.2983T>G p.L995V | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV54828891; called by muse, mutect2, varscan2
- FRK | c.1443G>T p.E481D | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.85); catalogued as COSV73383852; called by muse, mutect2, varscan2
- FRK | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV73383853; called by muse, mutect2, varscan2
- FRMPD3 | c.1924A>C p.N642H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as COSV52187716; called by muse, mutect2, varscan2
- FRZB | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1415736303, COSV54553283; called by muse, mutect2, varscan2
- FSHR | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); catalogued as COSV58619534; called by muse, mutect2, varscan2
- FTL | c.31A>G p.T11A | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV53169396; called by muse, mutect2, varscan2
- FUT1 | c.67T>G p.F23V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.9); PolyPhen probably damaging (0.977); catalogued as COSV55809969; called by muse, mutect2, varscan2
- FUT8 | c.1417C>T p.R473* (on ENST00000360689 / NM_001371534.1; = p.R310* on NM_004480.4) | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV61281308; called by muse, mutect2
- FYB1 | c.1843A>G p.I615V | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100684862; called by muse, mutect2
- FZD6 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763949530, COSV62470502; called by muse, mutect2, varscan2
- G6PC2 | c.693C>A p.D231E | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as COSV56371685; called by muse, mutect2, varscan2
- GABRA4 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV51924068; called by muse, mutect2, varscan2
- GABRB3 | c.751T>G p.Y251D | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54654002; called by muse, mutect2, varscan2
- GABRG3 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 20/37 reads (54%) | catalogued as rs933412981, COSV61512316; called by muse, mutect2, varscan2
- GABRR1 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV65618973; called by muse, mutect2, varscan2
- GALNT3 | c.533T>G p.F178C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs547467910, COSV67061469; called by muse, mutect2, varscan2
- GATC | c.292A>G p.N98D | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV57570145; called by muse, mutect2, varscan2
- GBF1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752314787, COSV64143413; called by muse, mutect2, varscan2
- GBP1 | c.1465A>G p.I489V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1392289386, COSV65082880; called by muse, mutect2, varscan2
- GCM2 | c.794G>T p.R265I | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs761297053, COSV65275193, COSV65276206; called by muse, mutect2, varscan2
- GCNA | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs748365021, COSV65466123; called by muse, mutect2, varscan2
- GFM2 | c.172T>C p.S58P | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.949); catalogued as COSV99714053; called by muse, mutect2
- GFPT2 | c.344T>G p.F115C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99517295; called by muse, mutect2, varscan2
- GGCX | c.2084+2T>C p.X695_splice | Splice Site (SNP) | VAF 13/31 reads (42%) | catalogued as COSV52087305; called by muse, mutect2, varscan2
- GHR | c.1592A>G p.D531G | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.733); catalogued as rs889434316, COSV50107664; called by muse, mutect2, varscan2
- GK2 | c.1218G>T p.E406D | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.999); catalogued as COSV62626271; called by muse, mutect2, varscan2
- GLB1 | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV56562153; called by muse, mutect2, varscan2
- GLDN | c.799T>C p.F267L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV59089185; called by muse, mutect2, varscan2
- GLI2 | c.395C>A p.S132Y | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369649251; called by muse, mutect2, varscan2
- GLI2 | c.1574A>C p.K525T (on ENST00000361492 / NM_001374353.1; = p.K542T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58036727; called by muse, mutect2, varscan2
- GLP1R | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs199796313, COSV64714509, COSV64715892; called by muse, mutect2, varscan2
- GLRA1 | c.935A>G p.D312G | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV51008372; called by muse, mutect2, varscan2
- GLRA3 | c.549A>C p.Q183H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56858797; called by muse, mutect2, varscan2
- GLS | c.1404C>A p.F468L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.106); catalogued as COSV100289728, COSV57840058, COSV57840430; called by muse, mutect2, varscan2
- GLT1D1 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs776480377, COSV55879424; called by muse, mutect2, varscan2
- GLT8D2 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV62561292; called by muse, mutect2, varscan2
- GLUD2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.027); catalogued as rs761101388, COSV60151496; called by muse, mutect2, varscan2
- GLYATL1 | c.536C>T p.S179F (on ENST00000317391 / NM_001354699.1; = p.S210F on NM_080661.4) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV55607708, COSV55610907; called by muse, mutect2, varscan2
- GMNN | c.42G>T p.E14D | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.187); catalogued as COSV57776647; called by muse, mutect2, varscan2
- GNB2 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.217); catalogued as rs760148387, COSV51940000; called by muse, mutect2, varscan2
- GOLGA4 | c.3836G>A p.R1279K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV62709695; called by muse, mutect2
- GOLGB1 | c.8567G>A p.R2856Q | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs529043980, COSV61462956; called by muse, mutect2, varscan2
- GOSR2 | c.79T>G p.F27V (on ENST00000393456 / NM_001321134.1; = p.F45V on NM_004287.5) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV99845939; called by muse, mutect2, varscan2
- GPAM | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as rs1312206205, COSV62080477; called by muse, mutect2, varscan2
- GPAT2 | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as rs748575171, COSV64003212; called by muse, mutect2, varscan2
- GPATCH1 | c.2658A>C p.Q886H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as COSV50111991; called by muse, mutect2, varscan2
- GPBP1 | c.601A>C p.N201H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV53310269; called by muse, mutect2, varscan2
- GPC5 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV65584137, COSV65609022; called by muse, mutect2, varscan2
- GPER1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.017); catalogued as rs201954771; called by muse, mutect2, varscan2
- GPR132 | c.455G>A p.G152D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61677689; called by muse, mutect2, varscan2
- GPR158 | c.1910G>T p.R637I | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as COSV66265740; called by muse, mutect2, varscan2
- GPR179 | c.6796G>T p.E2266* (on ENST00000621958; = p.E2265* on NM_001004334.4) | Nonsense Mutation (SNP) | VAF 26/51 reads (51%) | catalogued as rs561096333; called by muse, mutect2, varscan2
- GPR21 | c.115A>C p.T39P | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV65378862; called by muse, mutect2, varscan2
- GPR26 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV52933099; called by muse, mutect2
- GPR34 | c.314T>G p.F105C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV59363258; called by muse, mutect2, varscan2
- GPR75 | c.1262A>G p.K421R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61825537; called by muse, mutect2, varscan2
- GPR83 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147783996; called by mutect2, varscan2
- GPRC5D | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.063); catalogued as COSV57432451; called by muse, mutect2, varscan2
- GPX6 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV100724758; called by muse, mutect2, varscan2
- GRAMD1B | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59201508, COSV59206529; called by muse, mutect2, varscan2
- GRAMD1C | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs774536362, COSV63982133, COSV63983246; called by muse, mutect2, varscan2
- GRAMD1C | c.1791G>T p.E597D | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV63982140; called by muse, mutect2, varscan2
- GRAMD2A | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59032924; called by muse, mutect2, varscan2
- GRHL1 | c.1020C>A p.D340E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140008573; called by muse, mutect2, varscan2
- GRID1 | c.807T>G p.D269E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60018081, COSV60034080; called by muse, mutect2
- GRIP1 | c.904C>G p.L302V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54017748; called by muse, mutect2, varscan2
- GRIP2 | c.1547G>A p.R516Q (on ENST00000619221; = p.R419Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs572869583, COSV56120400; called by muse, mutect2, varscan2
- GRM5 | c.3515C>T p.S1172L (on ENST00000305447 / NM_001143831.2; = p.S1140L on NM_000842.4) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.906); catalogued as rs765131988, COSV59595365; called by muse, mutect2, varscan2
- GRM6 | c.1089G>T p.E363D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV51436137; called by muse, mutect2, varscan2
- GRM8 | c.204G>T p.K68N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.05); catalogued as COSV58810198; called by muse, mutect2, varscan2
- GRPR | c.69T>G p.S23R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV66669059; called by muse, mutect2, varscan2
- GRPR | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV66669062; called by muse, mutect2, varscan2
- GTF3C6 | c.269A>C p.K90T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.567); catalogued as COSV57332635, COSV57332919; called by muse, mutect2
- GTPBP8 | c.521A>G p.E174G | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV55606085; called by muse, mutect2, varscan2
- GUCY2F | c.1836C>A p.F612L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV54299520; called by muse, mutect2, varscan2
- HAUS1 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV56362887; called by muse, mutect2, varscan2
- HAUS3 | c.927T>G p.N309K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV54722068; called by muse, mutect2
- HAUS6 | c.169A>C p.I57L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1406996393, COSV65839626; called by muse, mutect2, varscan2
- HCN1 | c.2654G>A p.R885Q | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as rs775806199, COSV57498097; called by muse, mutect2, varscan2
- HCN1 | c.1404A>C p.K468N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV57498110; called by muse, mutect2, varscan2
- HCN1 | c.642G>T p.K214N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV57498118; called by muse, mutect2, varscan2
- HCRTR2 | c.681C>A p.F227L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV63794390, COSV63797243; called by muse, mutect2, varscan2
- HDAC3 | c.803G>A p.C268Y | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59495298; called by muse, mutect2, varscan2
- HDAC5 | c.2557A>G p.K853E | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV56817641; called by muse, mutect2, varscan2
- HDAC5 | c.284T>C p.F95S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56817650; called by muse, mutect2, varscan2
- HDAC8 | c.170T>G p.V57G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV65227604; called by muse, mutect2, varscan2
- HDAC9 | c.693A>C p.K231N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67769229; called by muse, mutect2, varscan2
- HDLBP | c.3109C>T p.R1037C | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs778670196, COSV60492902; called by muse, mutect2, varscan2
- HERC1 | c.8018C>T p.P2673L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs375309992; called by muse, mutect2, varscan2
- HERC2 | c.8639A>G p.D2880G | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55312428; called by muse, mutect2, varscan2
- HERC4 | c.1674G>T p.K558N | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV53269149; called by muse, mutect2, varscan2
- HERC5 | c.2384A>C p.K795T | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52039156; called by muse, mutect2
- HEXD | c.31T>A p.L11I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as COSV57339612; called by muse, mutect2, varscan2
- HEY2 | c.1014A>C p.*338Yext*25 | Nonstop Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV64239516; called by muse, mutect2
- HEYL | c.196T>G p.L66V | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100865268; called by muse, mutect2
- HFE | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.654); catalogued as rs776741897, COSV58512665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HHIPL2 | c.1564G>T p.D522Y | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58563691; called by muse, mutect2, varscan2
- HIVEP1 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV65098534; called by muse, mutect2, varscan2
- HIVEP1 | c.124T>G p.S42A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.607); catalogued as COSV65099517; called by mutect2, varscan2
- HIVEP3 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV99911508; called by muse, mutect2
- HK1 | c.2536C>T p.R846C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs146727978; called by muse, mutect2, varscan2
- HLA-A | c.640A>C p.T214P | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as COSV65138273; called by muse, mutect2, varscan2
- HLA-F | c.593A>G p.E198G | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV52574824; called by muse, mutect2
- HLF | c.453T>G p.G151= | Splice Region (SNP) | VAF 8/27 reads (30%) | catalogued as COSV56829025; called by muse, mutect2, varscan2
- HMMR | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as rs764564030, COSV62374059; called by muse, mutect2, varscan2
- HMX3 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as rs750180442, COSV63501529; called by muse, mutect2, varscan2
- HNF4A | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.028); catalogued as COSV57380606; called by muse, mutect2
- HNRNPU | c.853A>C p.T285P (on ENST00000283179; = p.T347P on NM_004501.3) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as COSV51689793; called by muse, mutect2, varscan2
- HOGA1 | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65706307; called by muse, mutect2
- HOXA11 | c.427T>A p.F143I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV50052897; called by muse, mutect2, varscan2
- HPGD | c.291G>T p.E97D | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV56661857; called by muse, mutect2, varscan2
- HPS5 | c.3279G>T p.E1093D (on ENST00000349215 / NM_181507.2; = p.E979D on NM_007216.4) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.295); catalogued as COSV61687191; called by muse, mutect2, varscan2
- HPS5 | c.2894A>C p.K965T (on ENST00000349215 / NM_181507.2; = p.K851T on NM_007216.4) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV61687194; called by muse, mutect2, varscan2
- HPS5 | c.1621G>T p.A541S (on ENST00000349215 / NM_181507.2; = p.A427S on NM_007216.4) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV61687200; called by muse, mutect2, varscan2
- HPS5 | c.613G>T p.E205* (on ENST00000349215 / NM_181507.2; = p.E91* on NM_007216.4) | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV62538918; called by muse, mutect2, varscan2
- HPSE2 | c.174G>T p.K58N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as rs1458018112, COSV65183294, COSV65194090; called by muse, mutect2, varscan2
- HRH4 | c.368G>T p.R123I | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1462297615, COSV56927561; called by mutect2, varscan2
- HSD17B4 | c.602A>C p.N201T (on ENST00000414835 / NM_001199291.3; = p.N176T on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as rs1226630841, COSV56334178; called by muse, mutect2, varscan2
- HSF4 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as COSV50456739; called by muse, mutect2, varscan2
- HSPA13 | c.12G>T p.E4D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as COSV53464832; called by muse, mutect2, varscan2
- HSPA8 | c.1695G>T p.E565D | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as COSV57083054; called by muse, mutect2, varscan2
- HTR2B | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.078); catalogued as rs781269061, COSV51449246; called by muse, mutect2, varscan2
- HTR3B | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52743097; called by muse, mutect2, varscan2
- HTR3C | c.85A>C p.T29P | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV59174540; called by muse, mutect2, varscan2
- HUWE1 | c.74A>C p.K25T | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV53337984; called by muse, mutect2, varscan2
- HYAL4 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV56137858; called by muse, mutect2
- HYDIN | c.13703T>G p.F4568C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV66637822; called by muse, mutect2, varscan2
- HYDIN | c.1415A>C p.K472T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55479780; called by muse, mutect2, varscan2
- ICAM3 | c.1204A>C p.I402L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.03); catalogued as COSV50328641; called by muse, mutect2, varscan2
- ICE1 | c.6026G>T p.R2009I | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56820842; called by muse, mutect2, varscan2
- IDE | c.2062T>G p.L688V | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.035); catalogued as COSV56422068; called by muse, mutect2, varscan2
- IDE | c.1402C>A p.L468I | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.486); catalogued as COSV56422076; called by muse, mutect2, varscan2
- IFI16 | c.1990G>T p.G664* (on ENST00000295809 / NM_001364867.2; = p.G608* on NM_005531.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/16 reads (56%) | catalogued as COSV55531961; called by muse, mutect2, varscan2
- IFIH1 | c.2691G>T p.K897N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV55125127, COSV55129383; called by muse, mutect2, varscan2
- IFIT2 | c.1213T>G p.S405A | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV51078237; called by muse, mutect2, varscan2
- IFNA6 | c.570A>C p.*190Yext*11 | Nonstop Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as COSV66506262; called by muse, mutect2, varscan2
- IFNGR1 | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as rs1562281992, COSV62991627; called by muse, mutect2, varscan2
- IGF2BP1 | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51729843; called by muse, mutect2, varscan2
- IGF2BP3 | c.1406G>T p.R469I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV51681375; called by muse, mutect2, varscan2
- IGHD | c.315G>T p.K105N | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as COSV101162803; called by muse, mutect2, varscan2
- IGSF10 | c.7435A>C p.I2479L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV56371744; called by muse, mutect2, varscan2
- IGSF10 | c.2521G>T p.E841* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV56782580; called by muse, mutect2, varscan2
- IHH | c.842A>G p.D281G | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.239); catalogued as COSV55392893; called by muse, mutect2
- IL12B | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV99180322; called by muse, mutect2, varscan2
- IL16 | c.2173T>G p.F725V (on ENST00000302987 / NM_172217.5; = p.F24V on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100267002; called by muse, mutect2, varscan2
- IL1R1 | c.1354A>C p.I452L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as COSV52105017; called by muse, mutect2
- IL1RAPL1 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as CM1513525, COSV56234144; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1430A>G p.D477G | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV61146330; called by muse, mutect2, varscan2
- IL1RL1 | c.393T>G p.I131M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747107463, COSV52113047; called by muse, mutect2, varscan2
- IL4R | c.959G>T p.R320M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV50139195, COSV50157784; called by muse, mutect2, varscan2
- IL6ST | c.2471C>T p.S824F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV61140259; called by muse, mutect2, varscan2
- INA | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV63975707, COSV63975918; called by muse, mutect2, varscan2
- INPP4B | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV53715022; called by muse, mutect2, varscan2
- INTS3 | c.2026C>A p.L676I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV59675816, COSV59679715; called by muse, mutect2, varscan2
- IQCG | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV54560811; called by muse, mutect2, varscan2
- IQCN | c.13+1G>A p.X5_splice | Splice Site (SNP) | VAF 15/28 reads (54%) | catalogued as COSV66572922; called by muse, mutect2, varscan2
- IQGAP3 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200764066, COSV63250315; called by muse, mutect2, varscan2
- IQSEC1 | c.2515T>G p.L839V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as COSV56221947; called by muse, mutect2, varscan2
- IRX4 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51471308; called by muse, mutect2, varscan2
- ISLR2 | c.1841G>T p.C614F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.1); catalogued as COSV62301764; called by muse, mutect2, varscan2
- ITGA1 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs757908946, COSV50877163; called by muse, mutect2
- ITGA8 | c.2769T>C p.N923= | Splice Region (SNP) | VAF 13/30 reads (43%) | catalogued as rs960439105, COSV65226080; called by muse, mutect2, varscan2
- ITGAE | c.2515G>A p.V839I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768639646, COSV53990455; called by muse, mutect2, varscan2
- ITGAL | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV63320670; called by muse, mutect2, varscan2
- ITGB2 | c.897C>T p.F299= | Splice Region (SNP) | VAF 29/73 reads (40%) | catalogued as rs150327269, COSV56608518; called by muse, mutect2, varscan2
- ITGB5 | c.2327A>C p.K776T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV56147153; called by muse, mutect2, varscan2
- ITIH4 | c.633T>G p.A211= | Splice Region (SNP) | VAF 30/67 reads (45%) | catalogued as COSV56572087; called by muse, mutect2, varscan2
- ITM2C | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs748390195, COSV100419677, COSV58398584; called by muse, mutect2, varscan2
- ITSN2 | c.1844C>A p.S615Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.459); catalogued as rs1270590523, COSV61944591; called by muse, mutect2
- IWS1 | c.476C>A p.S159Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV54866354, COSV54867015, COSV99767403; called by muse, mutect2, varscan2
- JADE3 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as rs782548118, COSV54464940; called by muse, mutect2, varscan2
- JAG1 | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54754442; called by muse, mutect2, varscan2
- JAK2 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV67589468; called by muse, mutect2, varscan2
- JAK2 | c.3034G>T p.E1012* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV67578992; called by muse, mutect2, varscan2
- KANSL1L | c.1560G>T p.E520D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.987); catalogued as COSV55990530, COSV55994720; called by muse, mutect2, varscan2
- KANSL2 | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV63479476; called by muse, mutect2, varscan2
- KCNA10 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV63904303; called by muse, mutect2, varscan2
- KCNA4 | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60251104; called by muse, mutect2, varscan2
- KCNA4 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs1406027339, COSV60251112; called by muse, mutect2, varscan2
- KCNA5 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV52904329; called by muse, mutect2, varscan2
- KCNA6 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1238844683, COSV99768330; called by muse, mutect2
- KCNC2 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs773079241, COSV100128298, COSV54364383; called by muse, mutect2, varscan2
- KCNG1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65368469; called by muse, mutect2, varscan2
- KCNH4 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs140956512; called by muse, mutect2, varscan2
- KCNJ16 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1044244559, COSV52251453; called by muse, mutect2, varscan2
- KCNK10 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs144714447; called by muse, mutect2, varscan2
- KCNK16 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as rs764549881, COSV64677446; called by muse, mutect2, varscan2
- KCNN2 | c.911C>A p.T304N (on ENST00000264773; = p.T516N on NM_021614.4) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53284787; called by muse, mutect2, varscan2
- KCNN4 | c.1179G>T p.E393D | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.875); catalogued as COSV99486932; called by muse, mutect2, varscan2
- KCNQ2 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60432345; called by muse, mutect2, varscan2
- KCNQ5 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as COSV59652891; called by muse, mutect2, varscan2
- KCNS1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1262411378, COSV60259531; called by muse, varscan2
- KCNT1 | c.1192C>T p.R398C (on ENST00000488444; = p.R417C on NM_020822.3) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs781342838, COSV53696772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCTD16 | c.446G>T p.R149I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV72577188; called by muse, mutect2, varscan2
- KCTD18 | c.624G>T p.K208N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63344023; called by muse, mutect2, varscan2
- KCTD7 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.245); catalogued as rs772773351, COSV51876457; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM5C | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62890822, COSV62891323; called by muse, mutect2
- KERA | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.531); catalogued as rs554112369, COSV57130184; called by muse, mutect2, varscan2
- KIAA0408 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0.037); catalogued as COSV64105511; called by muse, mutect2, varscan2
- KIAA1109 | c.4787A>C p.D1596A | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as COSV52665228; called by muse, mutect2, varscan2
- KIAA1109 | c.12814T>C p.Y4272H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52665243; called by muse, mutect2, varscan2
- KIAA1210 | c.1415C>A p.S472Y | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV68176017; called by muse, mutect2, varscan2
- KIAA1549 | c.3540G>T p.E1180D | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.182); catalogued as COSV54307953; called by muse, mutect2, varscan2
- KIAA1549L | c.4291G>A p.E1431K (on ENST00000321505; = p.E1728K on NM_012194.3) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs922623427, COSV58583690; called by muse, mutect2
- KIAA1586 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs372711155, COSV66056250, COSV66057408; called by muse, varscan2
- KIAA1841 | c.1938C>T p.D646= | Splice Region (SNP) | VAF 20/37 reads (54%) | catalogued as rs761990557, COSV54377967; called by muse, mutect2, varscan2
- KIAA2026 | c.4888A>C p.N1630H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV67353825; called by muse, mutect2, varscan2
- KIF1A | c.3869T>G p.V1290G (on ENST00000320389 / NM_001379639.1; = p.V1282G on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV57484514; called by muse, mutect2, varscan2
- KIF1B | c.444A>C p.E148D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55804863, COSV99822584; called by muse, mutect2, varscan2
- KIF21B | c.1718A>C p.K573T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV100143689; called by muse, mutect2
- KIF4A | c.1804C>A p.L602I | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65542017; called by muse, mutect2, varscan2
- KIF4B | c.2328G>T p.Q776H | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV70528344; called by muse, mutect2, varscan2
1,370 further variants in this file (983 protein-altering or splice-affecting, 343 silent, 44 other) are not listed here.
